Somatic mutation profile of tumor specimen TCGA-DD-A39X-01A (aliquot TCGA-DD-A39X-01A-11D-A20W-10) from TCGA case TCGA-DD-A39X, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 78.1 years (28,528 days).
Specimen TCGA-DD-A39X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c14dc6b9-d25b-4f8c-9cab-88255972d52f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A39X-11A (Solid Tissue Normal), aliquot TCGA-DD-A39X-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32152463-dac1-491e-9851-883e8ebaac44

The open-access MAF lists 68 somatic variants for this specimen: 54 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Nonsense Mutation 6, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.2512A>G p.I838V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs780819239, COSV60686927; called by muse, mutect2, varscan2
- ACOT13 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV57764586; called by muse, mutect2, varscan2
- AEBP1 | c.1440T>A p.N480K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV56258438; called by muse, mutect2, varscan2
- ALX3 | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 102/195 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100873880, COSV63928852; called by muse, mutect2, varscan2
- ANKMY2 | c.1190A>T p.E397V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV61011862; called by muse, mutect2, varscan2
- ANO3 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs758291457, COSV56793287; called by muse, mutect2, varscan2
- ARHGAP10 | c.385-2A>G p.X129_splice | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV60600235; called by muse, mutect2, varscan2
- ATAD1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100058375, COSV57757007; called by muse, mutect2, varscan2
- C9orf72 | c.1365T>G p.I455M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as COSV66163547; called by muse, mutect2, varscan2
- CCER1 | c.78G>A p.W26* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV62647190; called by muse, mutect2, varscan2
- CDH8 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1055288839, COSV54849423; called by muse, mutect2, varscan2
- CYP2C18 | c.360G>A p.W120* | Nonsense Mutation (SNP) | VAF 55/175 reads (31%) | catalogued as COSV53672595; called by muse, mutect2, varscan2
- DHX29 | c.2501A>G p.Q834R | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52418740; called by muse, mutect2, varscan2
- DNAH9 | c.9880G>A p.A3294T | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as rs368607572; called by muse, mutect2, varscan2
- FAT4 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as COSV67888256; called by muse, mutect2
- FERMT1 | c.1985A>T p.E662V | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54093792; called by muse, mutect2, varscan2
- FLG2 | c.2455G>A p.G819S | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV66169234; called by muse, mutect2
- GPSM1 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV61304325; called by muse, mutect2, varscan2
- GSDME | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs771163879, COSV61651627, COSV61651863; called by muse, mutect2
- GTF3C3 | c.2335C>T p.H779Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV55832380; called by muse, mutect2, varscan2
- HNRNPC | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as rs1367631708, COSV60145428; called by muse, mutect2, varscan2
- HS3ST6 | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs779606612, COSV53534981; called by muse, mutect2, varscan2
- IFNA7 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV53331326; called by muse, mutect2, varscan2
- KRT2 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs571471637, COSV59010753; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRTAP5-1 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 50/119 reads (42%) | PolyPhen benign (0.196); catalogued as COSV66299026; called by muse, mutect2, varscan2
- LILRB5 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs376519844; called by muse, mutect2, varscan2
- MGAT5 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56097035; called by muse, mutect2, varscan2
- MRC2 | c.3252C>A p.S1084R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV57640297; called by muse, mutect2, varscan2
- MTMR11 | c.1769G>A p.R590H (on ENST00000439741 / NM_001145862.2; = p.R518H on NM_181873.3) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs868984659, COSV54963886; called by muse, mutect2, varscan2
- MYOM1 | c.3940G>A p.G1314R | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55292956; called by muse, mutect2, varscan2
- NAV2 | c.3463C>G p.L1155V (on ENST00000396087 / NM_001244963.2; = p.L1132V on NM_145117.5) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV60659991; called by muse, mutect2, varscan2
- NKIRAS1 | c.214C>G p.P72A | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as COSV66248399; called by muse, mutect2, varscan2
- NVL | c.1668C>A p.F556L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55870674, COSV55872673, COSV55872950; called by muse, mutect2, varscan2
- OR5A1 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.894); catalogued as COSV57376909, COSV57378237; called by muse, mutect2, varscan2
- PCDHGA1 | c.2285A>G p.D762G | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.047); catalogued as COSV65296883; called by muse, mutect2, varscan2
- PCDHGB3 | c.884A>G p.D295G | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV53960743; called by muse, mutect2, varscan2
- SBNO2 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62320922; called by muse, mutect2, varscan2
- SEMA6D | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543020539, COSV60378107; called by muse, mutect2, varscan2
- SIRPB2 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV63123938; called by muse, mutect2, varscan2
- SLC17A2 | c.751T>C p.S251P | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55352480; called by muse, mutect2, varscan2
- SPEG | c.3574C>T p.R1192W | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767242646, COSV56670458; called by muse, mutect2, varscan2
- STXBP5 | c.2372G>T p.R791L (on ENST00000321680 / NM_001127715.2; = p.R755L on NM_139244.4) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV51653086; called by muse, mutect2, varscan2
- SVEP1 | c.8140T>C p.S2714P | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52839925; called by muse, mutect2
- TNRC6B | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.11); catalogued as COSV57297553; called by muse, mutect2, varscan2
- UGT2B28 | c.1337C>G p.S446* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV59432477; called by muse, mutect2
- ZNF106 | c.2095T>G p.L699V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV55517380; called by muse, mutect2, varscan2
- ZNF71 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as rs754884155, COSV60148197; called by muse, mutect2, varscan2
- ALB | c.1300_1301del p.R434Lfs*29 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- FCGBP | c.8899T>G p.S2967A | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by mutect2, varscan2
- FTCD | c.37_38insTTATGG p.S12_E13insVM | In Frame Ins (INS) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- GNB1 | c.791dup p.Y264* | Nonsense Mutation (INS) | VAF 56/143 reads (39%) | called by mutect2, pindel, varscan2
- GPR179 | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LDOC1 | c.220del p.Y74Tfs*4 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- SLC16A4 | c.1135_1136insT p.T379Ifs*2 | Frame Shift Ins (INS) | VAF 42/100 reads (42%) | called by mutect2, pindel*, varscan2*
- C9orf131 | c.2754A>G p.P918= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100397976; called by muse, mutect2
- CDCA2 | c.1152T>C p.F384= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100398780; called by muse, mutect2
- CEBPZ | c.348A>G p.K116= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV50017777; called by muse, mutect2, varscan2
- CELSR2 | c.1008C>T p.P336= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV54773170; called by muse, mutect2, varscan2
- DES | c.477G>A p.L159= | Silent (SNP) | VAF 2/11 reads (18%) | catalogued as rs1423370718; ClinVar: likely benign; called by muse, mutect2
- HCFC1 | c.3816G>A p.V1272= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV60072986; called by muse, mutect2, varscan2
- NKIRAS1 | c.213G>T p.L71= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV66248402; called by muse, mutect2, varscan2
- OGFRL1 | c.273A>G p.R91= | Silent (SNP) | VAF 19/129 reads (15%) | catalogued as rs1370413268, COSV64972046; called by muse, mutect2, varscan2
- OR1L6 | c.261C>T p.Y87= (on ENST00000373684; = p.Y51= on NM_001004453.2) | Silent (SNP) | VAF 44/213 reads (21%) | catalogued as COSV59028655; called by muse, mutect2, varscan2
- SAMD4B | c.1401C>G p.A467= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58751213, COSV58751748; called by muse, mutect2, varscan2
- SIM2 | c.522C>A p.G174= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51769337; called by muse, mutect2, varscan2
- TSHZ3 | c.1398G>C p.L466= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as COSV53673090; called by muse, mutect2
- VPS50 | c.1905T>A p.V635= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV58508016; called by muse, mutect2, varscan2
- LDB3 | c.896+6753C>T | Intron (SNP) | VAF 17/98 reads (17%) | catalogued as rs121908335, CM050286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
